Somatic mutation profile of tumor specimen TCGA-62-A46U-01A (aliquot TCGA-62-A46U-01A-11D-A24D-08) from TCGA case TCGA-62-A46U, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.2 years (25,998 days).
Specimen TCGA-62-A46U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7439e2f-4fa6-444a-9f07-f00dab5bb121.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-A46U-10A (Blood Derived Normal), aliquot TCGA-62-A46U-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f48e22d-25c6-4df2-82fb-3aa8748f185b

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 9/81 reads (11%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.51); PolyPhen benign (0.402); catalogued as CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; called by muse, mutect2, varscan2
- ACADSB | c.807G>A p.K269= | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100715298; called by muse, mutect2, varscan2
- ASXL1 | c.1630G>C p.D544H | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100040940, COSV60116235; called by muse, mutect2
- CACNG6 | c.670G>A p.G224S (on ENST00000252729 / NM_145814.1; = p.G153S on NM_031897.2) | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs775091115, COSV99403627; called by muse, mutect2, varscan2
- CCNH | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99907450; called by muse, mutect2
- COL7A1 | c.6341G>T p.G2114V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CD061396, COSV100097442; called by muse, mutect2, varscan2
- FKBPL | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.04); catalogued as COSV100913603; called by muse, mutect2, varscan2
- GJA9 | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs775570212, COSV100668159; called by muse, mutect2, varscan2
- KIAA1841 | c.1542G>T p.K514N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99694174; called by mutect2, varscan2
- LAIR1 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.741); catalogued as COSV100479838; called by muse, mutect2
- LTBP3 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100100258; called by muse, mutect2, varscan2
- MAGI2 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV100831762, COSV100836338; called by muse, mutect2, varscan2
- MCC | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100203147; called by muse, mutect2
- MGAM | c.312C>G p.D104E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV101516522; called by muse, mutect2, varscan2
- MS4A6E | c.406G>C p.V136L | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV100279222; called by muse, mutect2, varscan2
- NSMCE1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200970237, COSV99619344; called by muse, mutect2, varscan2
- OR10Q1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs746612596, COSV100372159, COSV57471918; called by muse, mutect2, varscan2
- OR6A2 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.583); catalogued as COSV100215810; called by muse, mutect2
- PDE9A | c.667T>A p.C223S | Missense Mutation (SNP) | VAF 32/425 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV99372115; called by muse, mutect2
- PURB | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as COSV101194995; called by muse, mutect2, varscan2
- RIPOR3 | c.2692G>A p.D898N | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99247070; called by muse, mutect2
- SBF2 | c.921C>A p.H307Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as COSV99815559; called by muse, mutect2
- SLC5A2 | c.1767C>G p.C589W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100393384; called by muse, mutect2, varscan2
- SRRM4 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57425075; called by muse, mutect2, varscan2
- STARD8 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1046647715, COSV52933201; called by muse, mutect2, varscan2
- TACC3 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV100508905; called by muse, mutect2, varscan2
- TAS2R41 | c.347A>T p.H116L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101281514, COSV68765458; called by muse, mutect2, varscan2
- TENM1 | c.4652G>T p.G1551V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100950763; called by muse, mutect2, varscan2
- TEX55 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV99817787; called by muse, mutect2, varscan2
- TP53INP2 | c.340A>C p.T114P | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV100873710; called by muse, mutect2, varscan2
- UGT1A5 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100530899; called by muse, mutect2
- UROS | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs548685819, COSV64223585; called by muse, mutect2, varscan2
- ESYT3 | c.1363_1370del p.N455Efs*5 | Frame Shift Del (DEL) | VAF 30/184 reads (16%) | called by mutect2, pindel, varscan2
- ALG12 | c.735C>T p.Y245= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV100427208; called by muse, mutect2, varscan2
- FNDC1 | c.3633C>A p.G1211= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99794535, COSV99796574; called by muse, mutect2
- FOXD4L4 | c.678C>T p.A226= | Silent (SNP) | VAF 26/319 reads (8%) | catalogued as rs1252488026; called by muse, mutect2, varscan2
- MKRN1 | c.879C>T p.N293= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99751859; called by muse, mutect2, varscan2
- NAT8 | c.249G>T p.T83= | Silent (SNP) | VAF 35/167 reads (21%) | catalogued as COSV99722071; called by muse, mutect2, varscan2
- SLC3A2 | c.1848G>A p.L616= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as COSV100101508; called by muse, mutect2, varscan2
- TLR4 | c.1191G>T p.G397= (on ENST00000355622 / NM_138554.5; = p.G357= on NM_003266.4) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV62922355, COSV62924211; called by muse, mutect2, varscan2
- TRIM33 | c.3327T>C p.F1109= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV100635698; called by muse, mutect2
- TRPC7 | c.651G>A p.S217= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs376839341; called by muse, mutect2, varscan2
- TTN | c.82365T>G p.T27455= (on ENST00000591111; = p.T20031= on NM_003319.4) | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV100626912; called by muse, mutect2, varscan2
- UBIAD1 | c.573C>G p.L191= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100954933; called by muse, mutect2, varscan2
- PRR12 | c.51+160C>G | Intron (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99882543; called by muse, mutect2, varscan2
